Somatic mutation profile of tumor specimen MMRF_1308_1_BM_CD138pos (aliquot MMRF_1308_1_BM_CD138pos_T2_KAS5U_L02447) from MMRF case MMRF_1308, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.3 years (19,463 days).
Specimen MMRF_1308_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 197a34ff-4809-41fd-9cbc-3906afcb0952.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1308_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1308_1_PB_Whole_C3_KAS5U_L02457; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c19e827b-14f4-46ec-a346-a1b0c62edf7c

The open-access MAF lists 125 somatic variants for this specimen: 35 protein-altering or splice-affecting, 18 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 39, Missense Mutation 28, Silent 18, Intron 17, 5'UTR 6, 5'Flank 5, 3'Flank 4, Frame Shift Del 3, Nonsense Mutation 1, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GBA | c.754T>A p.F252I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs381737, CM910173; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.1975A>G p.I659V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs1420934117; called by muse, mutect2, varscan2
- CCBE1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761881641, COSV67950286, COSV67951393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC146 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768291542; called by muse, mutect2, varscan2
- CPT2 | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs775793760; called by muse, mutect2, varscan2
- CYP4F2 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs761264883; called by muse, mutect2, varscan2
- FANCE | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs200535245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLT8D2 | c.322T>C p.F108L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV62563234; called by muse, mutect2
- LRP2 | c.2247C>G p.D749E | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV55550911; called by muse, mutect2, varscan2
- NRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752508313, COSV54744579, COSV54745979; called by muse, mutect2, varscan2
- OR10X1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1422494527, COSV63767248; called by muse, mutect2, varscan2
- PPCS | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65333617; called by muse, mutect2, varscan2
- PRRC2C | c.4642C>T p.Q1548* (on ENST00000367742; = p.Q1546* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 26/160 reads (16%) | catalogued as COSV58913679; called by muse, mutect2, varscan2
- TMSB4X | c.100+1G>A p.X34_splice | Splice Site (SNP) | VAF 45/50 reads (90%) | catalogued as COSV101020357; called by muse, mutect2, varscan2
- TRPM7 | c.1048A>G p.I350V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as rs1443943384, COSV57918557; called by muse, mutect2, varscan2
- CLHC1 | c.1438C>T p.L480F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CUBN | c.8624A>G p.D2875G | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FILIP1 | c.2816C>T p.T939I | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- FRMPD2 | c.2392C>A p.Q798K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKJ5 | chr2:88860550 del TAGTGAAAAATTACTTACGTT | Missense Mutation (DEL) | VAF 44/134 reads (33%) | called by pindel, varscan2
- KRT26 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 87/191 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LEO1 | c.1206A>C p.E402D | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- LTN1 | c.1335del p.L446Sfs*15 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- MAP3K2 | c.1599_1602del p.I533Mfs*19 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- MIGA2 | c.1643_1644insCAACCCAGAC p.L549Nfs*71 | Frame Shift Ins (INS) | VAF 52/114 reads (46%) | called by mutect2, pindel, varscan2
- OR1M1 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 66/361 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RNF168 | c.979_980del p.V327Lfs*7 | Frame Shift Del (DEL) | VAF 58/159 reads (36%) | called by pindel, varscan2
- SLC45A1 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRSF2 | c.6C>G p.S2R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SZT2 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TFCP2L1 | c.620A>T p.H207L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TNFAIP8L3 | c.859C>A p.L287I | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.123); called by muse, mutect2
- TPRA1 | c.-17-6C>T | Splice Region (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- UBC | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- ZNF280C | c.1475A>T p.H492L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- AL669918.1 | c.2448T>C p.P816= | Silent (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- CDR1 | c.198C>T p.D66= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- CTC1 | c.1923C>A p.P641= | Silent (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- DCHS2 | c.783G>A p.A261= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- FAM200A | c.735A>C p.R245= | Silent (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- FLG | c.11721C>T p.R3907= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs374091552; called by muse, mutect2, varscan2
- HAPLN1 | c.426T>A p.I142= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2
- IGLL5 | c.57T>A p.G19= | Silent (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- IMPA1 | c.366G>A p.V122= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- INSYN2A | c.90C>T p.Y30= | Silent (SNP) | VAF 27/207 reads (13%) | catalogued as rs778825802, COSV54760441; called by muse, mutect2, varscan2
- LINGO1 | c.1014C>A p.R338= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV62438452; called by muse, mutect2, varscan2
- MLXIP | c.2349G>A p.L783= | Silent (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- NEFM | c.1242A>C p.T414= | Silent (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- PMF1 | c.75T>A p.S25= | Silent (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- SAG | c.1053C>T p.V351= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as rs377460398; called by muse, mutect2
- ZDHHC5 | c.72A>G p.L24= | Silent (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- ZGRF1 | c.1590A>G p.V530= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as rs183927207; called by muse, mutect2, varscan2
- ZNF804A | c.444T>C p.C148= | Silent (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- ABAT | c.*897T>C | 3'UTR (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- ADGRL2 | c.*338T>C | 3'UTR (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- AL662791.2 | n.217A>G | RNA (SNP) | VAF 17/129 reads (13%) | called by muse, mutect2, varscan2
- ALX4 | c.*1450C>T | 3'UTR (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- AMER2 | chr13:25164224 G>A | 3'Flank (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- ANXA11 | c.*4433C>T | 3'UTR (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499405 C>T | 5'Flank (SNP) | VAF 26/69 reads (38%) | catalogued as rs185612860; called by muse, mutect2, varscan2
- ATL3 | c.*2395A>T | 3'UTR (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021275 C>T | 5'Flank (SNP) | VAF 38/103 reads (37%) | catalogued as rs765420246, COSV55847946, COSV55851575; called by muse, mutect2, varscan2
- C1orf122 | chr1:37807248 A>T | 5'Flank (SNP) | VAF 22/130 reads (17%) | called by muse, mutect2, varscan2
- CBR1 | c.289+31A>C | Intron (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- CCDC81 | c.-165A>G | 5'UTR (SNP) | VAF 24/130 reads (18%) | called by muse, mutect2, varscan2
- CDH26 | c.-222G>A | 5'UTR (SNP) | VAF 33/75 reads (44%) | catalogued as rs758760930; called by muse, mutect2, varscan2
- CDH7 | chr18:65883180 G>T | 3'Flank (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- CERS4 | c.468+42C>T | Intron (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- CTH | c.*261G>A | 3'UTR (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- DHRS11 | c.148-77G>C | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- DSG4 | c.-22C>T | 5'UTR (SNP) | VAF 25/176 reads (14%) | catalogued as rs747998720; called by muse, mutect2, varscan2
- EED | c.-187C>T | 5'UTR (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- EGR1 | c.-95A>T | 5'UTR (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- ESRRA | c.*747A>C | 3'UTR (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- FST | c.953-184del | Intron (DEL) | VAF 31/86 reads (36%) | catalogued as rs1412468031; called by mutect2, pindel, varscan2
- GINS3 | c.*251_*262del | 3'UTR (DEL) | VAF 9/92 reads (10%) | called by mutect2, pindel
- GPRC5B | c.*1928C>T | 3'UTR (SNP) | VAF 58/337 reads (17%) | catalogued as rs1451573964; called by muse, mutect2, varscan2
- GRAP2 | c.*280T>C | 3'UTR (SNP) | VAF 12/90 reads (13%) | catalogued as rs1008634550; called by mutect2, varscan2
- H4C5 | c.*160C>T | 3'UTR (SNP) | VAF 38/96 reads (40%) | catalogued as rs994096529; called by mutect2, varscan2
- HAND2 | c.-432G>A | 5'UTR (SNP) | VAF 69/148 reads (47%) | called by muse, mutect2, varscan2
- HDAC9 | c.1722+2203G>T | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- HDAC9 | c.1722+2204A>T | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- HGSNAT | c.*2480T>G | 3'UTR (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- HIPK2 | c.*2959G>A | 3'UTR (SNP) | VAF 19/112 reads (17%) | called by muse, mutect2, varscan2
- HNRNPU | c.634+1129C>T | Intron (SNP) | VAF 56/121 reads (46%) | catalogued as rs779983935, COSV51692635; called by muse, mutect2, varscan2
- HPCAL4 | c.*2128C>T | 3'UTR (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- IGSF5 | c.*414T>C | 3'UTR (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- IL17RD | c.*5262G>C | 3'UTR (SNP) | VAF 11/36 reads (31%) | catalogued as rs1403803464; called by muse, mutect2, varscan2
- ISCA1 | c.*751_*752del | 3'UTR (DEL) | VAF 11/91 reads (12%) | called by mutect2, pindel
- ISG20L2 | chr1:156728578 C>A | 5'Flank (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- KATNAL1 | c.*2838G>C | 3'UTR (SNP) | VAF 14/74 reads (19%) | called by muse, varscan2
- LMNA | c.357-3815G>A | Intron (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- LPP | c.*3015C>T | 3'UTR (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- MARCHF7 | c.*1424A>G | 3'UTR (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851314 G>A | 5'Flank (SNP) | VAF 69/153 reads (45%) | catalogued as rs573318832; called by muse, mutect2, varscan2
- NTRK3 | c.*6018T>C | 3'UTR (SNP) | VAF 10/64 reads (16%) | catalogued as rs1195896835; called by muse, mutect2, varscan2
- OTULIN | c.*3275T>C | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- PAPPA2 | c.*1082C>T | 3'UTR (SNP) | VAF 6/42 reads (14%) | catalogued as rs1557908180; called by muse, mutect2, varscan2
- PARD3 | c.*454T>A | 3'UTR (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- PDE4C | c.596-10C>T | Intron (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2
- PJA2 | c.*537T>A | 3'UTR (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- PLA2G6 | c.*415C>T | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- PLEK | c.*1609G>T | 3'UTR (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- POU2AF1 | c.*895T>A | 3'UTR (SNP) | VAF 80/186 reads (43%) | called by muse, mutect2, varscan2
- PPIL3 | c.*258A>G | 3'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- PPP2R5C | c.95-20463A>G | Intron (SNP) | VAF 63/129 reads (49%) | catalogued as rs1273843156; called by muse, mutect2, varscan2
- PRRC1 | c.1128+1742T>A | Intron (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- PYHIN1 | c.579+512G>A | Intron (SNP) | VAF 35/186 reads (19%) | called by muse, mutect2, varscan2
- RAB3IP | c.*872A>G | 3'UTR (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- RAG2 | chr11:36590413 G>A | 3'Flank (SNP) | VAF 34/66 reads (52%) | catalogued as rs747019244; called by muse, mutect2, varscan2
- SCN4B | c.*3521C>T | 3'UTR (SNP) | VAF 14/43 reads (33%) | catalogued as rs1305397664; called by muse, mutect2, varscan2
- SH3KBP1 | c.*785A>C | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- SH3RF3 | c.*519C>T | 3'UTR (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- SLC19A3 | c.-2-582T>A | Intron (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- SYP | c.102+84C>T | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as rs1316530455; called by muse, varscan2
- TACC2 | c.5835-2389G>A | Intron (SNP) | VAF 17/134 reads (13%) | called by muse, mutect2, varscan2
- TFAP2A | chr6:10397772 C>T | 3'Flank (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- TMEM201 | c.1160+218G>T | Intron (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- UBE2L6 | c.27+357C>A | Intron (SNP) | VAF 48/99 reads (48%) | called by muse, mutect2, varscan2
- USP31 | c.*563G>A | 3'UTR (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- UVSSA | c.*8939G>A | 3'UTR (SNP) | VAF 6/16 reads (38%) | catalogued as rs759644883, COSV99081932; called by muse, varscan2
- WDR41 | c.*280C>T | 3'UTR (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- ZFP37 | c.*2315A>C | 3'UTR (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- ZNF561 | c.*713A>T | 3'UTR (SNP) | VAF 10/71 reads (14%) | called by muse, varscan2
- ZNF561 | c.*648A>T | 3'UTR (SNP) | VAF 14/104 reads (13%) | called by muse, varscan2
